MMRF case MMRF_2160 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f24cfd7d-1605-4df1-b705-db6694fe745f

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 79 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.3 years (24,964 days); ISS stage: III; Days to last known disease status: 79 days; Days to last follow up: 79 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 60 days; Days to treatment end: 71 days.

Follow-up (2 entries)
- Days to follow up: -8 days; ECOG performance status: 1.
- Follow-up contact recording only the day: day 79.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Beta 2 Microglobulin 8.75 µg/mL.
- Total Protein 14.7 g/dL.
- Immunoglobulin M 0.21 g/L.
- Blood Urea Nitrogen 3.93 mmol/L.
- Platelets 117 ×10⁹/L.
- Creatinine 103 µmol/L.
- Calcium 2.6 mmol/L.
- Leukocytes 4.9 ×10⁹/L.
- Immunoglobulin A 86.5 g/L.
- Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL.
- Hemoglobin 5.21 mmol/L.
- Glucose 5.01 mmol/L.
- Albumin 26 g/L.
- M Protein 5.8 g/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 3.84 mg/dL.
- Absolute Neutrophil 3.1 ×10⁹/L.

Other clinical attributes
- Day -8: Weight: 40 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2160_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2160_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
